Somatic mutation profile of tumor specimen TCGA-61-2092-01A (aliquot TCGA-61-2092-01A-01W-0722-08) from TCGA case TCGA-61-2092, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 57.7 years (21,072 days).
Specimen TCGA-61-2092-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69a99d49-dd10-46e8-a1e3-9cf1b0410540.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2092-11A (Solid Tissue Normal), aliquot TCGA-61-2092-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2a78fc5-87f6-4b25-bf4e-0c55cdc565d0

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 15, Nonsense Mutation 5, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 92/236 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.623A>T p.D208V | Missense Mutation (SNP) | VAF 128/138 reads (93%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1464727668, COSV52685550, COSV52708074, COSV52744439; called by muse, mutect2, varscan2
- ADAR | c.2507C>T p.T836I | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as COSV52716632; called by muse, mutect2, varscan2
- ARHGAP17 | c.527T>C p.L176P | Missense Mutation (SNP) | VAF 209/436 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99253579; called by muse, mutect2, varscan2
- ARHGAP35 | c.1198G>T p.E400* | Nonsense Mutation (SNP) | VAF 86/233 reads (37%) | catalogued as COSV68330383, COSV68334239; called by muse, mutect2, varscan2
- CRB2 | c.1708C>T p.Q570* | Nonsense Mutation (SNP) | VAF 19/29 reads (66%) | catalogued as rs1564374557, COSV63503745; called by muse, mutect2, varscan2
- CXCR3 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as rs905571589, COSV65461770; called by muse, mutect2, varscan2
- DYNC1H1 | c.634A>G p.M212V | Missense Mutation (SNP) | VAF 147/411 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138182529; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGLN2 | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 242/552 reads (44%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.659); catalogued as rs756756342, COSV100393733, COSV58280327; called by muse, mutect2, varscan2
- EPX | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 13/181 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs376090047; called by muse, mutect2
- GDE1 | c.244C>G p.L82V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV62059592; called by muse, mutect2, varscan2
- GPNMB | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 192/515 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs753928951, COSV51699076; called by muse, mutect2, varscan2
- IL17A | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.237); catalogued as COSV100391559; called by muse, mutect2
- ITCH | c.1720C>T p.R574* (on ENST00000262650 / NM_001257137.3; = p.R533* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 152/323 reads (47%) | catalogued as COSV99392654; called by muse, mutect2, varscan2
- LRP2 | c.11200C>A p.P3734T | Missense Mutation (SNP) | VAF 106/197 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99788903; called by muse, mutect2, varscan2
- MACF1 | c.17461G>C p.E5821Q (on ENST00000372915; = p.E3863Q on NM_012090.5) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV57126590; called by muse, mutect2, varscan2
- MAGEA11 | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 107/199 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.089); catalogued as COSV100290550; called by muse, mutect2, varscan2
- MCTP2 | c.1958C>T p.S653F | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100537523; called by muse, mutect2
- MIF4GD | c.262C>T p.Q88* (on ENST00000325102 / NM_001370592.1; = p.Q122* on NM_020679.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV55453634; called by muse, mutect2, varscan2
- MMP27 | c.1138G>A p.V380I | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs202071510; called by muse, mutect2, varscan2
- MYH3 | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 138/834 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as COSV99878351; called by muse, varscan2
- NBAS | c.70T>A p.Y24N | Missense Mutation (SNP) | VAF 142/339 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99870227; called by muse, mutect2, varscan2
- NCKAP1 | c.2981A>G p.K994R | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as COSV100720320; called by muse, mutect2, varscan2
- NOP53 | c.47G>C p.S16T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV54409135; called by muse, mutect2, varscan2
- OCRL | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 178/384 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.179); catalogued as rs140494841, COSV100843466; called by muse, mutect2, varscan2
- OR5P2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 121/352 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs147652902; called by muse, mutect2, varscan2
- PCLO | c.8411C>T p.A2804V | Missense Mutation (SNP) | VAF 78/209 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61641458; called by muse, mutect2, varscan2
- PTPRO | c.1719G>A p.M573I | Missense Mutation (SNP) | VAF 435/1156 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV99840766; called by muse, mutect2, varscan2
- PXN | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs770650321, COSV57219437; called by muse, mutect2, varscan2
- RHOXF1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV54294877; called by muse, mutect2, varscan2
- RPGR | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV58836184; called by muse, mutect2, varscan2
- SHPRH | c.2812C>T p.H938Y | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs776782528, COSV99262200; called by muse, mutect2, varscan2
- SPCS2 | c.535G>A p.G179R | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as COSV99734428; called by muse, mutect2, varscan2
- TBC1D2B | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs755446116; called by muse, varscan2
- ZBTB14 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 94/251 reads (37%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.959); catalogued as COSV63696913; called by muse, mutect2, varscan2
- ZEB1 | c.2316C>A p.C772* | Nonsense Mutation (SNP) | VAF 146/342 reads (43%) | catalogued as rs143340752, COSV100314537; called by mutect2, varscan2
- ZNF30 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.201); catalogued as COSV57854188; called by muse, varscan2
- ZSCAN21 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs373816425, COSV52851028; called by muse, mutect2, varscan2
- SH3GLB1 | c.937dup p.L313Pfs*3 | Frame Shift Ins (INS) | VAF 177/666 reads (27%) | called by mutect2, pindel, varscan2
- UBL4B | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.295); called by mutect2, varscan2
- VRTN | c.1765G>T p.A589S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.015); called by muse, mutect2
- ZCCHC14 | c.1852A>G p.T618A (on ENST00000268616; = p.T755A on NM_015144.3) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by mutect2, varscan2
- AASS | c.90G>A p.R30= | Silent (SNP) | VAF 14/334 reads (4%) | catalogued as COSV100741806; called by muse, mutect2
- ACTL7A | c.108C>T p.G36= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV100453138; called by mutect2, varscan2
- ANKRD29 | c.105C>T p.G35= | Silent (SNP) | VAF 118/244 reads (48%) | catalogued as COSV52426368; called by muse, mutect2, varscan2
- CPSF3 | c.1011C>A p.S337= | Silent (SNP) | VAF 15/274 reads (5%) | catalogued as COSV99432895; called by muse, mutect2
- DYRK2 | c.993G>A p.S331= (on ENST00000344096 / NM_006482.3; = p.S258= on NM_003583.4) | Silent (SNP) | VAF 112/283 reads (40%) | catalogued as rs1156433770, COSV59845719; called by muse, mutect2, varscan2
- EBF1 | c.225C>T p.Y75= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs998358011, COSV58182094; called by muse, mutect2, varscan2
- MMUT | c.12T>C p.A4= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV51275050; called by muse, mutect2, varscan2
- MOCOS | c.1002C>T p.T334= | Silent (SNP) | VAF 44/415 reads (11%) | catalogued as COSV99733534; called by muse, mutect2, varscan2
- PCDHGA11 | c.804G>A p.T268= | Silent (SNP) | VAF 118/197 reads (60%) | catalogued as rs377701820; called by muse, mutect2, varscan2
- PI4K2B | c.693G>A p.K231= | Silent (SNP) | VAF 59/186 reads (32%) | catalogued as rs765084289, COSV53511760, COSV53512954; called by muse, mutect2, varscan2
- RASAL1 | c.91C>T p.L31= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV55656928; called by muse, mutect2, varscan2
- SLC15A2 | c.1998C>T p.F666= | Silent (SNP) | VAF 126/338 reads (37%) | catalogued as COSV99815566; called by muse, mutect2, varscan2
- STX11 | c.852C>A p.P284= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100845498; called by muse, varscan2
- TRPM1 | c.3510G>A p.K1170= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as rs1566996083, COSV56636394; called by muse, mutect2, varscan2
- ZNF441 | c.1500T>C p.D500= | Silent (SNP) | VAF 63/179 reads (35%) | catalogued as COSV63540059; called by muse, mutect2, varscan2
- SERPINA13P | n.1041G>C | RNA (SNP) | VAF 10/55 reads (18%) | called by muse, varscan2
